Surgical pathology report (de-identified scan), TCGA case TCGA-XM-A8RD, project TCGA-THYM (Thymoma), tissue source site MSKCC, specimen TCGA-XM-A8RD-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED] Accession #: [REDACTED]
MRN: [REDACTED] Service: [REDACTED]
Account: [REDACTED] Date of Procedure: [REDACTED]
DOB: [REDACTED] (Age: [REDACTED] F Date of Receipt: [REDACTED]
Physician: [REDACTED] Date of Report: [REDACTED]
CC: [REDACTED]
Patient Address: [REDACTED]

....

Clinical Diagnosis & History:

year old female with recurrent papillary thyroid carcinoma with mass in left upper anterior mediastinum.

Specimens Submitted:

1: SP: Thymectomy (fs)

DIAGNOSIS:

1. THYMUS, THYMECTOMY:
- THYMOMA, WHO TYPE B2 (4.2 CM IN GREATEST DIMENSION), ENCAPSULATED WITH FOCAL MICROSCOPIC INVASION INTO INTRATHYMIC FAT.
- UNINVOLVED THYMIC TISSUE IS INVOLUTED.
- MARGIN IS FREE OF TUMOR.
- ONE BENIGN LYMPH NODE.

NOTE: TUMOR CELLS ARE POSITIVE FOR AE1/AE3. CD1A, CD3 AND CD99 STAINS HIGHLIGHT THE BACKGROUND LYMPHOCYTES.

I ATTEST THAT THE ABOVE DIAGNOSIS IS BASED UPON MY PERSONAL EXAMINATION OF THE SLIDES (AND/OR OTHER MATERIAL), AND THAT I HAVE REVIEWED AND APPROVED THIS REPORT.

*** Report Electronically Signed Out ***

Gross Description:

1).The specimen is received fresh for frozen section and is labeled "thymectomy". It consists of one flat piece of tan yellow fibroadipose tissue measuring 12 x 6x 5 cm. One surface is inked black and the other surface is inked blue. The specimen is bisected and reveals one well-circumscribed tan firm nodule measuring 4.2 x 2.5 x 2.0 cm. The cut surface of the nodule is fleshy with focal areas of hemorrhage. TPS and photos are taken. Representative sections are submitted.

Summary of sections:

** Continued on next page **

ICD-6-3
Thymoma, type B2,
malignant 8584/3
Site: Thymus C379
JUS/12/14

[page 2 of 2]
SURGICAL PATHOLOGY REPORT

Patient: [REDACTED]
MRN: [REDACTED]
Account #: [REDACTED]

Accession #: [REDACTED]
Physician: [REDACTED]
Service: [REDACTED]
Date of Report: [REDACTED]

Page 2 of 2

FSC frozen section control
N - nodule
RS - remaining tissue

Summary of Sections:
Part 1: SP: Thymectomy (fs)

Block	Sect. Site	PCs
1	fsc	1
5	N	5
2	RS	2

Intraoperative Consultation:
Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Thymectomy (fs): Thymoma
PERMANENT DIAGNOSIS: SAME

Note: The diagnoses given in this section pertain only to the tissue sample examined at the time of the intraoperative consultation.

1. FROZEN SECTION DIAGNOSIS: SP: Thymectomy (fs): Thymoma
PERMANENT DIAGNOSIS: SAME

** End of Report **

Patient on Synthroid prior to tumor procurement;
[REDACTED]

Source: NCI Genomic Data Commons file 3362b759-0f4a-4ada-b0a6-2973cf551414 (TCGA-XM-A8RD.430654EC-8A02-42A7-BD0F-538ED79A813C.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).